Somatic mutation profile of tumor specimen 0DACIT from CCDI case PBBJVH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.6 years (6,077 days).
Specimen 0DACIT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99e7c0f7-d31a-43ac-9c88-dbf5849fd41a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DACIY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebfc44c6-c04c-4e25-9374-9eb8b1fae485

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 162/741 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.295del p.S99Pfs*24 | Frame Shift Del (DEL) | VAF 104/498 reads (21%) | catalogued as rs1555526593, COSV53312510; ClinVar: pathogenic; called by mutect2, varscan2
- HGF | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 101/1307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55945734; called by muse, mutect2
- IVL | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 70/908 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1216377138; called by muse, mutect2
- TEAD1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 101/631 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV57563493; called by muse, mutect2, varscan2
- MBD3L5 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 48/1371 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.55); called by muse, mutect2
- PPEF1 | c.1465A>T p.T489S | Missense Mutation (SNP) | VAF 113/997 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PPRC1 | c.1050dup p.Q351Afs*8 | Frame Shift Ins (INS) | VAF 92/591 reads (16%) | called by mutect2, varscan2
- ZBTB20 | c.1784A>C p.K595T (on ENST00000474710 / NM_001164342.2; = p.K522T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/598 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- CD40LG | c.642C>T p.S214= | Silent (SNP) | VAF 102/879 reads (12%) | catalogued as rs761216947, COSV65698321; called by muse, mutect2, varscan2
- AP2A2 | c.*34G>C | 3'UTR (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- OR7D2 | c.-52T>A | 5'UTR (SNP) | VAF 12/97 reads (12%) | called by muse, varscan2
- ZNF133 | c.*52A>G | 3'UTR (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
